Somatic mutation profile of tumor specimen TCGA-AA-3697-01A (aliquot TCGA-AA-3697-01A-01D-1719-10) from TCGA case TCGA-AA-3697, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 77.7 years (28,367 days).
Specimen TCGA-AA-3697-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c43b9ebc-405e-4ba7-b37d-759146c2d68a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3697-11A (Solid Tissue Normal), aliquot TCGA-AA-3697-11A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdb5cf75-2149-4a73-b4a2-64a0c4a4d0af

The open-access MAF lists 215 somatic variants for this specimen: 167 protein-altering or splice-affecting, 45 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 45, Nonsense Mutation 14, Frame Shift Del 8, Splice Site 7, Frame Shift Ins 3, 5'UTR 1, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 37/74 reads (50%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.197T>C p.F66S | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53965679; called by muse, mutect2, varscan2
- ABCG8 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV55391475; called by muse, mutect2, varscan2
- ACTR1B | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100008053, COSV56703523; called by muse, mutect2
- ACTRT2 | c.392T>G p.F131C | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65759052; called by muse, mutect2, varscan2
- ADGRV1 | c.16997C>T p.A5666V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs371528462, COSV101316402; called by muse, mutect2, varscan2
- AKTIP | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs528168629, COSV50874135; called by muse, mutect2, varscan2
- ALMS1 | c.3250G>A p.D1084N | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as COSV52505287; called by muse, mutect2, varscan2
- ANKRD35 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375460193, COSV62909900; called by muse, mutect2, varscan2
- AP3B2 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs750705900, COSV55607735; called by muse, mutect2, varscan2
- APC | c.3925G>T p.E1309* | Nonsense Mutation (SNP) | VAF 57/233 reads (24%) | catalogued as rs1321583762, CD084022, CD941590, CM920052, COSV57321386, COSV57334587, COSV99971982; called by muse, mutect2, varscan2
- API5 | c.1157T>C p.V386A | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.371); catalogued as COSV66632718; called by muse, mutect2, varscan2
- APOBEC3G | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 123/374 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.221); catalogued as rs775955420, COSV68469989; called by muse, mutect2, varscan2
- ARHGAP36 | c.1365C>G p.N455K | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as COSV52265107; called by muse, mutect2, varscan2
- ARMH3 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64233829; called by muse, mutect2, varscan2
- ATP11A | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52108282; called by muse, mutect2
- BASP1 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV59469966; called by muse, varscan2
- BUB1 | c.2784_2785insG p.F929Vfs*6 | Frame Shift Ins (INS) | VAF 28/165 reads (17%) | catalogued as COSV57062019; called by mutect2, pindel, varscan2
- C2orf80 | c.497G>A p.S166N | Missense Mutation (SNP) | VAF 148/857 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV58016043; called by muse, mutect2, varscan2
- CACNA2D3 | c.1046T>G p.L349R | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55524089; called by muse, mutect2, varscan2
- CAPSL | c.595A>T p.I199F | Missense Mutation (SNP) | VAF 140/309 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV68437526; called by muse, mutect2, varscan2
- CARD10 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771075851, COSV52655175; called by muse, varscan2
- CCDC191 | c.1978+1G>C p.X660_splice | Splice Site (SNP) | VAF 29/133 reads (22%) | catalogued as COSV55671004; called by muse, mutect2, varscan2
- CCDC82 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1443181182, COSV53592641, COSV53594020; called by muse, mutect2, varscan2
- CCKBR | c.714C>A p.Y238* | Nonsense Mutation (SNP) | VAF 68/483 reads (14%) | catalogued as COSV58098518, COSV58099724; called by muse, mutect2, varscan2
- CD248 | c.1709C>A p.P570Q | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV60936008; called by muse, mutect2, varscan2
- CFAP53 | c.544G>C p.A182P | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV68351561; called by muse, mutect2, varscan2
- CFAP91 | c.722T>C p.I241T | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1256522294, COSV56339912; called by muse, mutect2, varscan2
- CHD7 | c.6287A>T p.H2096L | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM060215, COSV71108061; called by muse, mutect2, varscan2
- CMTR1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 208/393 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs140898368, COSV65089829; called by muse, mutect2, varscan2
- COL22A1 | c.1450-1G>C p.X484_splice | Splice Site (SNP) | VAF 12/75 reads (16%) | catalogued as COSV57329234; called by muse, mutect2, varscan2
- COMMD8 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67500311; called by muse, mutect2, varscan2
- COPS6 | c.664A>T p.I222L | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100385131; called by muse, mutect2, varscan2
- CPT1B | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773375016, COSV56415782; called by muse, mutect2, varscan2
- CSF2RB | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs770407372, COSV53256425; called by muse, mutect2, varscan2
- CSMD1 | c.8300C>T p.T2767M (on ENST00000520002; = p.T2766M on NM_033225.6) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.167); catalogued as rs546161313, COSV59298663; called by muse, mutect2, varscan2
- CSMD3 | c.4094A>C p.K1365T (on ENST00000297405 / NM_001363185.1; = p.K1261T on NM_052900.3) | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52153245, COSV99845982; called by muse, mutect2, varscan2
- CSNK1A1L | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); catalogued as rs1396915431, COSV65789478; called by muse, mutect2
- CXorf66 | c.1078A>C p.N360H | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV65168998; called by muse, mutect2, varscan2
- CYP3A7 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 22/248 reads (9%) | catalogued as COSV60480937; called by muse, mutect2
- DCAF12L1 | c.892C>A p.L298M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV64421366; called by muse, mutect2, varscan2
- DCAKD | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777222686, COSV60201883; called by muse, mutect2, varscan2
- DCBLD1 | c.326-1G>A p.X109_splice | Splice Site (SNP) | VAF 31/132 reads (23%) | catalogued as COSV51639326; called by muse, mutect2, varscan2
- DLG2 | c.434+1G>C p.X145_splice | Splice Site (SNP) | VAF 29/150 reads (19%) | catalogued as COSV54630312; called by muse, mutect2, varscan2
- DNAH11 | c.11852G>T p.G3951V | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100180565; called by muse, mutect2, varscan2
- DOCK10 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 72/352 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV51361039; called by muse, mutect2, varscan2
- DOCK11 | c.5026G>A p.E1676K | Missense Mutation (SNP) | VAF 190/619 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52235641; called by muse, mutect2, varscan2
- DUOX1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV50993246; called by muse, mutect2
- E2F7 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 86/287 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1413623148, COSV59738402; called by muse, mutect2, varscan2
- EEF2KMT | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV69863247; called by muse, mutect2, varscan2
- EFCAB13 | c.2277C>A p.N759K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.205); catalogued as COSV58946368, COSV58946892; called by muse, mutect2, varscan2
- EGFL6 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs867038905, COSV100789887, COSV63633252; called by muse, mutect2, varscan2
- EML5 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs754145545, COSV61343270; called by muse, mutect2, varscan2
- EPB41L5 | c.563G>C p.R188T | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55350311; called by muse, mutect2, varscan2
- ERCC6 | c.3868G>T p.A1290S | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV63388700; called by muse, mutect2, varscan2
- ESCO1 | c.1747C>T p.H583Y | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as COSV52518893; called by muse, mutect2, varscan2
- ESRRG | c.1370A>C p.K457T | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV63149033, COSV63153130; called by muse, mutect2, varscan2
- FAM118A | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV53416490; called by muse, mutect2, varscan2
- FARSB | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV56047927, COSV99918602; called by muse, mutect2, varscan2
- FAT4 | c.3890C>T p.S1297L | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1025986676, COSV101272671; called by muse, mutect2, varscan2
- FCHSD1 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV71300621; called by muse, mutect2, varscan2
- FER1L6 | c.3436G>T p.V1146L | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV67548855; called by muse, mutect2, varscan2
- FNIP2 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1256373490, COSV52436862; called by muse, mutect2, varscan2
- FNTA | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 110/200 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV56489525; called by muse, mutect2, varscan2
- GPR139 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV58501653; called by muse, mutect2, varscan2
- GSTP1 | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); catalogued as COSV66992318; called by muse, mutect2, varscan2
- HDDC2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 97/295 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59532006; called by muse, mutect2, varscan2
- HINFP | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.105); catalogued as COSV63431775; called by muse, mutect2, varscan2
- IFT122 | c.3532C>T p.R1178C (on ENST00000348417 / NM_052989.3; = p.R1119C on NM_018262.4) | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs549826483, COSV99959775; called by muse, varscan2
- IL18 | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54780947; called by muse, mutect2, varscan2
- INTS7 | c.2389C>A p.Q797K | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65343925; called by muse, mutect2, varscan2
- IRX5 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as COSV58058645; called by muse, mutect2
- KCNH5 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs745970423, COSV59752965, COSV59755413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM2B | c.3692G>A p.R1231Q | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.652); catalogued as rs782061809, COSV65639005; called by muse, mutect2, varscan2
- KLRC2 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 71/729 reads (10%) | catalogued as COSV67899583; called by muse, mutect2
- KRT33B | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs747784843, COSV52440540; called by muse, mutect2, varscan2
- MAP1B | c.3785C>A p.S1262Y | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1374630565, COSV57095806; called by muse, mutect2, varscan2
- MAP3K4 | c.4111A>G p.M1371V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as COSV62331214; called by muse, mutect2, varscan2
- MCF2 | c.713T>A p.L238* | Nonsense Mutation (SNP) | VAF 331/615 reads (54%) | catalogued as COSV58480529; called by muse, mutect2, varscan2
- MCF2L2 | c.1297C>A p.L433M | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100193786; called by muse, mutect2
- METTL7B | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs776219569, COSV57693174; called by muse, mutect2, varscan2
- METTL9 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 111/350 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.141); catalogued as rs778358052, COSV99193658; called by muse, mutect2, varscan2
- MMP15 | c.644C>A p.T215N | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV54679170; called by muse, mutect2
- MUC17 | c.3821G>C p.S1274T | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV60283314; called by muse, mutect2, varscan2
- MYH8 | c.3643C>T p.R1215W | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1403404409, COSV67961741; called by muse, mutect2, varscan2
- MYO18B | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as COSV59126310, COSV59129122; called by muse, mutect2, varscan2
- NFASC | c.1987G>A p.V663I (on ENST00000339876 / NM_001378329.1; = p.V659I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.155); catalogued as rs148589226; called by muse, mutect2, varscan2
- NPHP1 | c.625-1G>A p.X209_splice | Splice Site (SNP) | VAF 47/297 reads (16%) | catalogued as COSV57207288; called by muse, mutect2, varscan2
- NUAK1 | c.1728C>A p.S576R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54601573; called by muse, mutect2
- OTOGL | c.5051G>A p.G1684E (on ENST00000547103; = p.G1675E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54014843; called by muse, mutect2, varscan2
- OTX2 | c.14T>A p.L5H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV59765646, COSV59767430; called by muse, mutect2
- OVGP1 | c.27G>T p.G9= | Splice Region (SNP) | VAF 22/169 reads (13%) | catalogued as COSV63857950; called by muse, mutect2
- OVGP1 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs191208264, COSV63857954; called by muse, mutect2
- PCDHA1 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs886883971, COSV65373264; called by muse, mutect2, varscan2
- PGBD4 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56629233, COSV99854964; called by muse, mutect2, varscan2
- PHIP | c.4409A>T p.K1470I | Missense Mutation (SNP) | VAF 121/537 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV51502504; called by muse, mutect2, varscan2
- PHKA1 | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 89/168 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs782021614, COSV59803683; called by muse, mutect2, varscan2
- PHLDB2 | c.147T>G p.F49L | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV67309321; called by muse, mutect2, varscan2
- PIP5K1C | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746930314, COSV58951000; called by muse, mutect2, varscan2
- PPP2R3A | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 47/109 reads (43%) | catalogued as COSV53861063; called by muse, mutect2, varscan2
- PROCA1 | c.1064C>T p.S355F (on ENST00000439862 / NM_001366301.1; = p.S327F on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/272 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV56385556; called by muse, mutect2, varscan2
- PRPF4B | c.2733+2T>C p.X911_splice | Splice Site (SNP) | VAF 52/164 reads (32%) | catalogued as COSV61783669; called by muse, mutect2, varscan2
- PRRC2C | c.4553del p.N1518Mfs*4 (on ENST00000367742; = p.N1516Mfs*4 on NM_015172.4) | Frame Shift Del (DEL) | VAF 22/116 reads (19%) | catalogued as rs759081735; called by mutect2, varscan2
- PRSS54 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54689246; called by muse, mutect2, varscan2
- PTGER2 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55418434; called by muse, mutect2
- RAB6A | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV60177887; called by muse, mutect2, varscan2
- RAET1L | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 93/522 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53952725; called by muse, mutect2, varscan2
- RET | c.2795G>C p.S932T | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60689776; called by muse, mutect2, varscan2
- ROR1 | c.2666C>T p.S889L | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.076); catalogued as COSV64284956; called by muse, mutect2, varscan2
- RPS6KA6 | c.1907G>T p.R636L | Missense Mutation (SNP) | VAF 138/598 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV53117701; called by muse, mutect2, varscan2
- SGCB | c.594G>T p.L198F | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV67340712; called by muse, mutect2, varscan2
- SIN3A | c.1112A>T p.D371V | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64582230; called by muse, mutect2, varscan2
- SLC5A12 | c.1789C>T p.H597Y | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.081); catalogued as COSV68448342; called by muse, varscan2
- SLCO1B1 | c.1663C>T p.H555Y | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57008725; called by muse, mutect2, varscan2
- SNRPA1 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as COSV54257301; called by muse, mutect2, varscan2
- SNRPA1 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV54257311; called by muse, mutect2, varscan2
- SNX9 | c.1734C>G p.Y578* | Nonsense Mutation (SNP) | VAF 59/146 reads (40%) | catalogued as COSV101094150; called by muse, varscan2
- SOAT1 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV62653322; called by muse, mutect2, varscan2
- SRY | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 45/79 reads (57%) | catalogued as COSV67170356; called by muse, mutect2, varscan2
- STIL | c.2320G>T p.V774L | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV54548891; called by muse, mutect2, varscan2
- STXBP5L | c.3040A>C p.M1014L | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56505438; called by muse, mutect2, varscan2
- SUN3 | c.102C>A p.D34E | Missense Mutation (SNP) | VAF 125/270 reads (46%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.003); catalogued as COSV52049115, COSV52049450; called by muse, mutect2, varscan2
- SYNE1 | c.4055T>G p.V1352G (on ENST00000367255 / NM_182961.4; = p.V1359G on NM_033071.3) | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV99576504; called by muse, mutect2, varscan2
- SYT1 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271381185, COSV54038985; called by muse, mutect2, varscan2
- SYT1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs750035344, COSV54038994; called by muse, mutect2, varscan2
- SYT16 | c.1814A>G p.E605G | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70855610; called by muse, mutect2, varscan2
- TAAR1 | c.154A>T p.K52* | Nonsense Mutation (SNP) | VAF 65/356 reads (18%) | catalogued as COSV51588008; called by muse, mutect2, varscan2
- TANC2 | c.2437G>T p.G813* | Nonsense Mutation (SNP) | VAF 35/312 reads (11%) | catalogued as COSV67332153; called by muse, mutect2, varscan2
- TANC2 | c.2438G>T p.G813V | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67332158, COSV99067300; called by muse, mutect2, varscan2
- TCN2 | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV53190919; called by muse, mutect2, varscan2
- TCN2 | c.123G>A p.W41* | Nonsense Mutation (SNP) | VAF 34/160 reads (21%) | catalogued as COSV53190925; called by muse, mutect2, varscan2
- TIAM1 | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as COSV54542593; called by muse, mutect2, varscan2
- TLE1 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1423737388, COSV64719905; called by muse, mutect2, varscan2
- TMEM132D | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 87/489 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101398941, COSV70598748; called by muse, mutect2, varscan2
- TOM1L1 | c.650G>C p.R217P | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV61946920; called by muse, varscan2
- TOM1L1 | c.674A>G p.E225G | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1284121497, COSV61946926; called by muse, varscan2
- TOMM34 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 70/1215 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756307089, COSV65688915; called by muse, mutect2
- TSHZ1 | c.815G>T p.R272L (on ENST00000580243 / NM_001308210.2; = p.R227L on NM_005786.6) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59007295, COSV59011489; called by muse, mutect2, varscan2
- TTC37 | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV62454100; called by muse, mutect2, varscan2
- TUBGCP3 | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs373823517; called by muse, mutect2, varscan2
- UNC13C | c.2077A>G p.K693E | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.257); catalogued as rs1242222333, COSV99522427; called by muse, mutect2, varscan2
- USP15 | c.236T>G p.L79R | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54789638; called by muse, mutect2, varscan2
- VPS13D | c.6152A>T p.K2051M | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV50627842; called by muse, mutect2, varscan2
- WDR61 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV51216600; called by muse, mutect2, varscan2
- XIRP2 | c.2285T>G p.L762R (on ENST00000628543; = p.L937R on NM_152381.6) | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754516318, COSV54689020; called by muse, mutect2, varscan2
- XPO6 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58964534; called by muse, mutect2
- YIPF4 | c.638T>C p.L213S | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV53213244; called by muse, mutect2, varscan2
- ZBTB4 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs17854295, COSV60978009; called by muse, mutect2, varscan2
- ZFAT | c.3329C>T p.A1110V | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs773605523, COSV64736169; called by muse, mutect2, varscan2
- ZFHX4 | c.7723G>T p.A2575S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.054); catalogued as COSV50637111; called by muse, mutect2, varscan2
- ZFYVE27 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 80/167 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as rs368842487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZMYND8 | c.3358-1G>C p.X1120_splice (on ENST00000311275 / NM_001363741.2; = p.X1094_splice on NM_012408.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 22/100 reads (22%) | catalogued as COSV53684584; called by muse, mutect2
- ZNF185 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.058); catalogued as COSV100248639; called by muse, varscan2
- ZNF354A | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100234637; called by muse, mutect2
- ZNF586 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as rs757248739, COSV66972295; called by muse, mutect2, varscan2
- ZNF646 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.219); catalogued as rs774529327, COSV56212427; called by muse, mutect2, varscan2
- ZNF831 | c.1486G>A p.V496M | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs755204091, COSV64038493; called by muse, mutect2
- CTNNA2 | c.1235del p.K412Rfs*3 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2*, pindel, varscan2*
- DEFB118 | c.110_111del p.Q37Lfs*23 | Frame Shift Del (DEL) | VAF 40/378 reads (11%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.12638_12651del p.S4213Ffs*8 | Frame Shift Del (DEL) | VAF 16/109 reads (15%) | called by mutect2, pindel, varscan2
- KYNU | c.993_994del p.S332Kfs*13 | Frame Shift Del (DEL) | VAF 68/465 reads (15%) | called by mutect2, pindel, varscan2
- LINS1 | c.1661dup p.S555Kfs*28 | Frame Shift Ins (INS) | VAF 51/232 reads (22%) | called by mutect2, pindel, varscan2
- NTN1 | c.367_376del p.E123Cfs*19 | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- PEG3 | c.2471_2486del p.T824Nfs*10 | Frame Shift Del (DEL) | VAF 27/178 reads (15%) | called by mutect2, pindel, varscan2
- SHCBP1L | c.1017dup p.Y340Ifs*3 | Frame Shift Ins (INS) | VAF 59/217 reads (27%) | called by mutect2, pindel, varscan2
- SLC4A7 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); called by muse, mutect2
- TLR7 | c.47_48del p.F16* | Frame Shift Del (DEL) | VAF 76/277 reads (27%) | called by mutect2, pindel, varscan2
- AATF | c.853T>C p.L285= | Silent (SNP) | VAF 61/328 reads (19%) | called by muse, mutect2, varscan2
- ADH1B | c.783A>C p.G261= | Silent (SNP) | VAF 87/674 reads (13%) | catalogued as COSV59295646; called by muse, mutect2, varscan2
- ALS2CL | c.1536G>A p.A512= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs760332683, COSV59670739; called by muse, mutect2, varscan2
- APC | c.3348T>C p.G1116= | Silent (SNP) | VAF 68/143 reads (48%) | catalogued as COSV57333005; called by muse, mutect2, varscan2
- ARHGEF4 | c.1380C>T p.N460= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs201353514, COSV58119369; called by muse, mutect2, varscan2
- ART5 | c.660C>T p.R220= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs770807658, COSV63364243; called by muse, mutect2
- CACTIN | c.2148C>T p.Y716= | Silent (SNP) | VAF 64/166 reads (39%) | catalogued as rs375029543; called by muse, mutect2, varscan2
- CAPRIN2 | c.1911T>C p.S637= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV51831492; called by muse, mutect2, varscan2
- CHD8 | c.4474C>T p.L1492= (on ENST00000646647 / NM_001170629.2; = p.L1213= on NM_020920.4) | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV63218884; called by muse, mutect2, varscan2
- COL22A1 | c.1149G>A p.A383= | Silent (SNP) | VAF 98/298 reads (33%) | catalogued as rs746255639, COSV57326795, COSV57356565; called by muse, mutect2, varscan2
- COPS6 | c.663G>T p.L221= | Silent (SNP) | VAF 33/209 reads (16%) | catalogued as COSV57994947; called by muse, mutect2, varscan2
- CYP4F11 | c.6G>A p.P2= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs767868619, COSV56126191; called by muse, mutect2
- DNAH8 | c.11484T>A p.S3828= | Silent (SNP) | VAF 86/333 reads (26%) | catalogued as COSV59433428; called by muse, mutect2, varscan2
- DUSP8 | c.282G>C p.R94= | Silent (SNP) | VAF 44/232 reads (19%) | catalogued as COSV59029686; called by muse, mutect2
- EEFSEC | c.819C>T p.F273= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs1318978584, COSV54621782, COSV54631275; called by muse, mutect2, varscan2
- GPC2 | c.774C>T p.I258= | Silent (SNP) | VAF 145/287 reads (51%) | catalogued as rs755977904, COSV52785526; called by muse, mutect2, varscan2
- HCN1 | c.2181G>T p.L727= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as COSV57499791; called by muse, mutect2, varscan2
- HEPACAM | c.726C>T p.Y242= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs1030383504, COSV53429173, COSV99035976; called by muse, mutect2
- HRNR | c.2415C>A p.G805= | Silent (SNP) | VAF 64/155 reads (41%) | catalogued as rs1055109716, COSV64255869; called by muse, mutect2, varscan2
- HS6ST2 | c.675C>T p.G225= | Silent (SNP) | VAF 68/89 reads (76%) | catalogued as COSV63711652; called by muse, mutect2, varscan2
- IRX1 | c.360C>T p.Y120= | Silent (SNP) | VAF 76/203 reads (37%) | catalogued as COSV57358565; called by muse, mutect2, varscan2
- JPH1 | c.1674C>T p.N558= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as rs1459148848, COSV60609681; called by muse, mutect2, varscan2
- KCNH4 | c.1581C>T p.D527= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as rs1382569454, COSV52916145; called by muse, mutect2, varscan2
- LASP1 | c.711C>T p.D237= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs746197131, COSV58803016; called by muse, mutect2
- MDH1B | c.673C>T p.L225= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV65588920, COSV65589344; called by muse, mutect2, varscan2
- MPDZ | c.957A>G p.A319= | Silent (SNP) | VAF 80/336 reads (24%) | catalogued as COSV59937481, COSV59939536; called by muse, mutect2, varscan2
- OR10W1 | c.348C>T p.A116= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV67720299, COSV67720600; called by muse, mutect2, varscan2
- OXER1 | c.819G>C p.V273= | Silent (SNP) | VAF 42/67 reads (63%) | catalogued as COSV54310224; called by muse, mutect2, varscan2
- PCDH10 | c.1155C>T p.R385= | Silent (SNP) | VAF 48/89 reads (54%) | catalogued as COSV52090057; called by muse, mutect2, varscan2
- PCDHA1 | c.714C>T p.N238= | Silent (SNP) | VAF 36/165 reads (22%) | catalogued as rs782103349, COSV65373257; called by muse, mutect2, varscan2
- PCDHA7 | c.1278C>T p.T426= | Silent (SNP) | VAF 98/339 reads (29%) | catalogued as rs782249131, COSV65342960; called by muse, mutect2, varscan2
- PCDHGA5 | c.393G>A p.P131= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs746438679, COSV53917293; called by muse, mutect2, varscan2
- PCDHGB1 | c.1182G>A p.S394= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs1189071192, COSV53917278; called by muse, mutect2, varscan2
- PLEKHN1 | c.1194C>T p.G398= (on ENST00000379409; = p.G346= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/150 reads (35%) | catalogued as rs759304010, COSV58021205; called by muse, mutect2, varscan2
- PON2 | c.489T>C p.L163= | Silent (SNP) | VAF 94/334 reads (28%) | catalogued as rs546665604, COSV56000911; called by muse, mutect2, varscan2
- PRPF38B | c.1473T>C p.S491= | Silent (SNP) | VAF 153/391 reads (39%) | catalogued as COSV64223594; called by muse, mutect2, varscan2
- RXFP2 | c.1389G>C p.L463= | Silent (SNP) | VAF 36/480 reads (8%) | catalogued as COSV100034582, COSV53638407; called by muse, mutect2
- SHANK3 | c.1050C>A p.P350= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV53185005; called by muse, mutect2
- SIGLEC12 | c.918G>A p.T306= (on ENST00000291707 / NM_053003.4; = p.T188= on NM_033329.2) | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs375071831; called by muse, mutect2, varscan2
- SLAIN1 | c.795A>T p.G265= (on ENST00000466548; = p.G2= on NM_144595.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/260 reads (6%) | catalogued as rs1311628772, COSV99935455; called by muse, mutect2
- TMEM132D | c.858G>T p.L286= | Silent (SNP) | VAF 88/494 reads (18%) | catalogued as COSV70598750; called by muse, mutect2, varscan2
- TPP1 | c.1122C>T p.F374= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV54993725; called by muse, mutect2, varscan2
- WDR61 | c.210G>T p.V70= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV51216604; called by muse, mutect2, varscan2
- ZNF106 | c.4614G>A p.Q1538= | Silent (SNP) | VAF 129/206 reads (63%) | catalogued as COSV55514833, COSV99783251; called by muse, mutect2, varscan2
- ZNF804B | c.3519C>G p.L1173= | Silent (SNP) | VAF 36/219 reads (16%) | catalogued as COSV60821123; called by muse, mutect2, varscan2
- CDKL1 | n.181C>T | RNA (SNP) | VAF 51/215 reads (24%) | catalogued as rs779976238; called by muse, mutect2, varscan2
- MICAL3 | c.2242-3490G>T | Intron (SNP) | VAF 21/67 reads (31%) | catalogued as COSV52894390; called by muse, mutect2, varscan2
- RAP1GAP | c.-28C>G | 5'UTR (SNP) | VAF 8/45 reads (18%) | catalogued as COSV51570164; called by muse, mutect2, varscan2
